Somatic mutation profile of tumor specimen TCGA-P5-A736-01A (aliquot TCGA-P5-A736-01A-11D-A32B-08) from TCGA case TCGA-P5-A736, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 44.6 years (16,300 days).
Specimen TCGA-P5-A736-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 256aa91e-f7a4-4ce3-bd48-82a4b918e20a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A736-10A (Blood Derived Normal), aliquot TCGA-P5-A736-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc264da1-c9be-4344-88bf-26e8d0c9382b

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Frame Shift Del 4, Nonsense Mutation 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 21/53 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.587G>C p.R196P | Missense Mutation (SNP) | VAF 20/31 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs483352697, CM984587, COSV52667931, COSV52674826, COSV52678297; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.3847G>A p.A1283T | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.169); catalogued as COSV100972701; called by muse, mutect2
- AC004922.1 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.87); catalogued as COSV99501359, COSV99501455; called by muse, mutect2
- ATRX | c.6281C>G p.S2094* | Nonsense Mutation (SNP) | VAF 17/129 reads (13%) | catalogued as COSV64883331; called by muse, mutect2, varscan2
- CACNA1H | c.4700C>T p.A1567V | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as rs773757935, COSV61986618; called by muse, mutect2
- CAMSAP3 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs376504713, COSV99349925; called by muse, mutect2, varscan2
- DAB2IP | c.1855A>G p.S619G (on ENST00000408936; = p.S591G on NM_032552.3) | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV99406161; called by muse, mutect2, varscan2
- F2RL1 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149001132; called by muse, mutect2, varscan2
- MGAT4C | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV59829391; called by muse, mutect2, varscan2
- MTMR8 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs764878210, COSV100878429; called by muse, mutect2, varscan2
- NIBAN3 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs772492810, COSV99962469; called by muse, mutect2, varscan2
- NLRP8 | c.533_535del p.F178del | In Frame Del (DEL) | VAF 10/89 reads (11%) | catalogued as rs773103156; called by pindel, varscan2
- PCLO | c.3413C>A p.P1138H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV100436416, COSV61614795; called by muse, mutect2, varscan2
- RYR2 | c.10757T>C p.V3586A | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.969); catalogued as COSV100772224; called by muse, mutect2
- TRIM13 | c.647A>C p.D216A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100078515; called by muse, mutect2, varscan2
- UGT3A2 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as rs199567567; called by mutect2, varscan2
- NUDT4 | c.464_465del p.T155Sfs*7 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by pindel, varscan2
- RTTN | c.137_138del p.F46Sfs*27 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | called by mutect2, pindel
- STEAP4 | c.60_61del p.E20Dfs*9 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by pindel, varscan2
- ZNF273 | c.1260_1261del p.H420Qfs*6 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.2034G>A p.K678= (on ENST00000611781; = p.K622= on NM_052997.2) | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs866879335, COSV64610428, COSV64624442; called by muse, mutect2, varscan2
- GPR75 | c.861A>G p.G287= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs369707376; called by muse, mutect2, varscan2
- WNT7A | c.168C>T p.P56= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs145281257; called by muse, mutect2, varscan2
- ZNF442 | c.1599C>T p.V533= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV99664478, COSV99664545; called by muse, mutect2, varscan2
- MBNL1 | c.174+40175T>C | Intron (SNP) | VAF 7/108 reads (6%) | catalogued as COSV99221107; called by muse, mutect2
